Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A432, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A432-01A (Primary Tumor).

Procurement Date: Laterality: Papillary carcinoma ·

Path Report: Tumor type: Papillary carcinoma

Tumor size: 2.5x2x1cm

Laterality: left .

Focality: Unifocal .

Extrathyroidal extension: No

TSH: 0.8 mIU/ml

Noted		

7/24/12

ICD-O-3
carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS
C73.9

8-3-12
R0

Source: NCI Genomic Data Commons file 3cf74291-86d5-448b-a0b2-a29a4dee4c5a (TCGA-E8-A432.709BEB00-E3BB-41EE-B600-5AAE02867871.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).